Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7469, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7469-01A (Primary Tumor).

Microscopic

Sections demonstrate a markedly hypercellular glial neoplasm. The tumor cells in many areas have round, small nuclei with little atypia. In these areas, mitotic figures are rare. In other areas, the nuclei are larger and more angular. Here up to eight mitoses per 10 high power fields are seen. Blood vessels are prominent and true microvascular proliferation is not seen. Several foci of nonpalisading tumor necrosis are present. Overall, the tumor cells have few processes and many have small perinuclear halos.

Addendum discussion:

The calculated MIB-1 labeling index is 16.1% consistent with a high grade glioma.

Final Addendum Pathology Report

Insular Tumor, including area worrisome for high grade, biopsies and resection:

Anaplastic oligodendroglioma (WHO grade III)

MIB-1 labeling index = 16.1%

Source: NCI Genomic Data Commons file 05485f51-bcfe-421f-9958-3cb4c23ab0f7 (TCGA-HT-7469.D79EA6E7-CE40-4E9A-9E82-61A6A517A571.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).